Somatic mutation profile of tumor specimen 0DLV38 from CCDI case PBBZLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,309 days).
Specimen 0DLV38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57aacbf9-c679-4c75-9f01-182a35e0694a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLV2X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8b30e02-22a0-474a-bc9b-8aa5164cf3e2

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 584/1256 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 662/985 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFAP61 | c.2837C>T p.T946M | Missense Mutation (SNP) | VAF 731/1512 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140045830; called by muse, mutect2, varscan2
- KIAA1217 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 264/866 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1037444599; called by muse, mutect2, varscan2
- POSTN | c.2485C>T p.R829* | Nonsense Mutation (SNP) | VAF 366/649 reads (56%) | catalogued as rs751429947, COSV65712204; called by muse, mutect2, varscan2
- QSOX2 | c.1683C>G p.H561Q | Missense Mutation (SNP) | VAF 243/991 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1564288355; called by muse, mutect2, varscan2
- TRPV4 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 309/940 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as rs775092573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYPK | c.151A>T p.N51Y | Missense Mutation (SNP) | VAF 211/973 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MAGEL2 | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 458/999 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ZNF527 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 70/1336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- APOA4 | c.480C>T p.Y160= | Silent (SNP) | VAF 398/584 reads (68%) | catalogued as rs538954345, COSV100759252, COSV63360358; called by muse, mutect2, varscan2
- CSMD3 | c.3873A>T p.G1291= (on ENST00000297405 / NM_001363185.1; = p.G1187= on NM_052900.3) | Silent (SNP) | VAF 573/1286 reads (45%) | called by muse, mutect2, varscan2
- DDX27 | c.1402C>T p.L468= | Silent (SNP) | VAF 843/1751 reads (48%) | called by muse, mutect2, varscan2
- INPP4A | c.1368G>A p.R456= | Silent (SNP) | VAF 76/1012 reads (8%) | catalogued as COSV99302374; called by muse, mutect2
- P2RY2 | c.501C>T p.P167= | Silent (SNP) | VAF 20/698 reads (3%) | catalogued as COSV100232807, COSV60775428, COSV60776674; called by muse, mutect2
- TENM4 | c.8223C>T p.F2741= | Silent (SNP) | VAF 237/829 reads (29%) | catalogued as rs267603207, COSV53612529; called by muse, mutect2, varscan2
- WNT1 | c.15G>A p.A5= | Silent (SNP) | VAF 85/271 reads (31%) | called by muse, mutect2, varscan2
- DENND1B | c.921+58T>G | Intron (SNP) | VAF 27/521 reads (5%) | called by muse, mutect2
- MUC19 | c.271-30T>C | Intron (SNP) | VAF 18/353 reads (5%) | called by muse, mutect2
- ZNF784 | c.78+31del | Intron (DEL) | VAF 200/418 reads (48%) | called by mutect2, varscan2
